Somatic mutation profile of tumor specimen TCGA-ZJ-AAXA-01A (aliquot TCGA-ZJ-AAXA-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAXA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 64.6 years (23,603 days).
Specimen TCGA-ZJ-AAXA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55e1feb4-0b28-4289-a58c-e29aa858f33e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXA-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXA-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a6f405c-a64b-48d8-896b-39ff41fe8f91

The open-access MAF lists 81 somatic variants for this specimen: 52 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 28, Nonsense Mutation 5, Splice Site 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD10 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771986771, COSV100564138; called by muse, varscan2
- ASB10 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs142736544, CM1514030; called by muse, mutect2, varscan2
- C1QL4 | c.335T>G p.F112C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99226828; called by muse, mutect2, varscan2
- CEP350 | c.5512G>A p.E1838K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1177981919, COSV62602924; called by muse, mutect2, varscan2
- CRNKL1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.846); catalogued as rs767978683, COSV55630926; called by muse, mutect2, varscan2
- CSMD3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99833549, COSV99836169; called by muse, mutect2, varscan2
- DHRS3 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.074); catalogued as rs754683233, COSV66108501; called by muse, mutect2, varscan2
- ENGASE | c.1876C>G p.H626D | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100285774; called by muse, mutect2, varscan2
- ESPN | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100911438; called by muse, mutect2, varscan2
- FLG | c.10562C>T p.S3521F | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs767216620, COSV64241865; called by muse, mutect2, varscan2
- FOXQ1 | c.582G>C p.W194C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99723280; called by muse, mutect2, varscan2
- GAB2 | c.1144G>T p.V382F (on ENST00000361507 / NM_080491.3; = p.V344F on NM_012296.3) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.049); catalogued as rs1565114490, COSV100416484; called by muse, mutect2, varscan2
- GALNT11 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.655); catalogued as COSV100231802; called by muse, mutect2
- GDI2 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100050445; called by muse, mutect2, varscan2
- HORMAD1 | c.253T>C p.C85R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200394759, COSV100464090; called by muse, mutect2, varscan2
- HTATSF1 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99511636; called by muse, mutect2, varscan2
- KAT6B | c.5534A>G p.N1845S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs779773468, COSV99768005; called by muse, mutect2, varscan2
- KLK15 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1326706289, COSV56825765; called by muse, mutect2, varscan2
- KMT2C | c.7443-1G>C p.X2481_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as COSV51333129, COSV51430440, COSV51435943; called by mutect2, varscan2
- LAYN | c.601G>A p.E201K (on ENST00000375615 / NM_001258390.1; = p.E193K on NM_178834.5) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV100986226; called by muse, mutect2, varscan2
- MAFF | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV100633106; called by muse, mutect2, varscan2
- MARF1 | c.5054C>T p.S1685F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV100705889; called by muse, mutect2, varscan2
- MCF2L2 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 43/143 reads (30%) | catalogued as COSV100192459; called by muse, mutect2, varscan2
- MED12L | c.726G>A p.Q242= | Splice Region (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99852996; called by muse, mutect2, varscan2
- MIA3 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV100719424; called by muse, mutect2, varscan2
- MXRA5 | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV99476849, COSV99478185; called by muse, mutect2, varscan2
- NLGN4X | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52035829, COSV99321623; called by muse, mutect2
- NPR1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs1186749259, COSV100902018; called by muse, mutect2, varscan2
- NRXN3 | c.3079C>T p.R1027C (on ENST00000335750 / NM_001330195.2; = p.R654C on NM_004796.6) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140301017; called by muse, mutect2, varscan2
- OTOF | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99717605; called by muse, mutect2, varscan2
- PKHD1L1 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs371118948; called by muse, mutect2, varscan2
- PQBP1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99504251; called by muse, mutect2, varscan2
- PTBP1 | c.1076-2A>T p.X359_splice (on ENST00000349038 / NM_031991.4; = p.X385_splice on NM_002819.5) | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100608639; called by muse, mutect2, varscan2
- RAB33B | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.001); catalogued as COSV99978193; called by muse, mutect2, varscan2
- RBMS2 | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100008497; called by muse, varscan2
- RIT2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs1422428322, COSV100450849; called by muse, mutect2, varscan2
- RNF38 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as COSV99425026; called by muse, mutect2, varscan2
- RUNX1T1 | c.797G>A p.R266Q (on ENST00000265814 / NM_001198628.1; = p.R239Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359364143, COSV99750353; called by muse, mutect2, varscan2
- SIGLEC10 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189044911, COSV100218939, COSV59484341; called by muse, mutect2, varscan2
- SLC38A6 | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99712105; called by muse, mutect2, varscan2
- SMS | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65113687; called by muse, mutect2, varscan2
- SPAG9 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs1013371947, COSV100005150; called by muse, mutect2, varscan2
- SPTA1 | c.3520G>T p.E1174* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV63752437, COSV63759051; called by muse, mutect2, varscan2
- TBX1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.045); catalogued as COSV100284171; called by muse, mutect2, varscan2
- TRPC1 | c.829C>T p.R277W (on ENST00000476941 / NM_001251845.2; = p.R243W on NM_003304.4) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763511368, COSV56424578; called by muse, mutect2, varscan2
- UGT1A6 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs115279280, COSV100530238; called by muse, mutect2, varscan2
- UHRF1 | c.1069G>A p.E357K (on ENST00000612630 / NM_001290050.1; = p.E370K on NM_013282.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as rs879913506, COSV99503513; called by muse, mutect2, varscan2
- ZMYM3 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100077845; called by muse, mutect2, varscan2
- ZNF112 | c.979G>A p.E327K (on ENST00000337401 / NM_001083335.2; = p.E321K on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100495742; called by muse, mutect2, varscan2
- ZNF236 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99470306; called by muse, mutect2, varscan2
- ZNF770 | c.1610T>C p.V537A | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100695943; called by muse, mutect2, varscan2
- ZNF790 | c.1448G>A p.C483Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100764817; called by muse, mutect2, varscan2
- AHDC1 | c.3270C>T p.S1090= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99899266; called by muse, mutect2, varscan2
- CACNA1E | c.2493G>A p.R831= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100702475; called by muse, mutect2, varscan2
- CARF | c.1644C>G p.L548= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100247644; called by muse, mutect2, varscan2
- CGB8 | c.96C>T p.I32= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100032015; called by mutect2, varscan2
- CPAMD8 | c.348G>A p.Q116= (on ENST00000651564; = p.Q69= on NM_015692.5) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV52237379, COSV99359348; called by muse, mutect2, varscan2
- CPNE1 | c.774T>A p.S258= (on ENST00000352393; = p.S263= on NM_003915.5) | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100467479; called by muse, mutect2, varscan2
- DNAH1 | c.6879C>T p.I2293= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1232241335, COSV101325682; called by muse, mutect2, varscan2
- ESPN | c.894G>A p.L298= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- GRPR | c.1101C>T p.S367= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs773980405, COSV66668961; called by muse, mutect2, varscan2
- HTR2C | c.924A>G p.K308= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99349252; called by muse, mutect2, varscan2
- ITGB8 | c.1032A>G p.Q344= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99751407; called by muse, mutect2, varscan2
- ITPRIP | c.1284C>T p.L428= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as COSV53392296; called by muse, mutect2, varscan2
- KIF3C | c.489G>A p.K163= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV53099500, COSV53099828; called by muse, mutect2, varscan2
- LIMCH1 | c.159C>T p.L53= | Silent (SNP) | VAF 41/55 reads (75%) | catalogued as rs376424238; called by muse, mutect2, varscan2
- LTA4H | c.768G>A p.Q256= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99957079; called by muse, mutect2, varscan2
- MID1IP1 | c.171C>T p.G57= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100423707; called by muse, mutect2, varscan2
- MXRA5 | c.1497G>A p.L499= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99476846; called by muse, mutect2, varscan2
- NCDN | c.1584C>T p.L528= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs772058400, COSV100621995; called by muse, varscan2
- NOL9 | c.1182C>T p.F394= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs752367303, COSV100891457; called by muse, mutect2, varscan2
- OR10J5 | c.528C>T p.F176= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV58386234, COSV58388083; called by muse, mutect2, varscan2
- OR5M3 | c.300C>T p.F100= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100392500; called by muse, mutect2, varscan2
- PDZD7 | c.1176C>T p.L392= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100931623; called by muse, mutect2, varscan2
- PGBD5 | c.900G>A p.R300= (on ENST00000525115; = p.R369= on NM_001258311.2) | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs768993092, COSV100358572; called by muse, mutect2, varscan2
- PLXNA3 | c.2844C>T p.S948= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs199634043, COSV63754085; called by muse, mutect2, varscan2
- SLC29A4 | c.423C>G p.L141= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV99786766; called by muse, mutect2, varscan2
- SLCO3A1 | c.268C>T p.L90= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100575363; called by muse, mutect2, varscan2
- TRNAU1AP | c.261G>T p.G87= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100867883; called by muse, mutect2, varscan2
- WTAP | c.687G>A p.L229= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- MIR1270 | chr19:20397595 G>C | 3'Flank (SNP) | VAF 36/171 reads (21%) | called by muse, mutect2, varscan2
